Somatic mutation profile of tumor specimen 0E2B28 from CCDI case PBCVHI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E2B28: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92e975b7-ce0c-4660-9455-22794dda8005.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0YD2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b7f89af-19e4-41a1-adc8-c52dd115af55

The open-access MAF lists 101 somatic variants for this specimen: 58 protein-altering or splice-affecting, 24 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 24, Intron 12, Frame Shift Del 7, 5'UTR 3, 3'Flank 2, 3'UTR 2, Frame Shift Ins 2, Nonsense Mutation 1, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 186/1328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221587520; called by muse, mutect2, varscan2
- CAVIN2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 215/963 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs367846421; called by muse, mutect2, varscan2
- CENPE | c.4981G>A p.E1661K | Missense Mutation (SNP) | VAF 289/1654 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as rs1401040037; called by muse, mutect2, varscan2
- CHMP5 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 204/1523 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV56302917; called by mutect2, varscan2
- CREBBP | c.2900G>C p.S967T | Missense Mutation (SNP) | VAF 85/658 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); catalogued as COSV52129438; called by muse, mutect2, varscan2
- FCGBP | c.5841G>A p.E1947= | Splice Region (SNP) | VAF 22/168 reads (13%) | catalogued as rs1398468567; called by muse, mutect2, varscan2
- GNE | c.1498G>C p.G500R (on ENST00000396594 / NM_001128227.3; = p.G469R on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 217/574 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM139088; called by muse, mutect2, varscan2
- GOLGA6L9 | c.1117G>C p.A373P | Missense Mutation (SNP) | VAF 10/444 reads (2%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1348789502; called by muse, mutect2
- GRID1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV60014973; called by muse, varscan2
- HAX1 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 34/657 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV55168363; called by muse, mutect2
- IK | c.1177C>G p.P393A | Missense Mutation (SNP) | VAF 149/719 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV70257386; called by muse, mutect2, varscan2
- KRT84 | c.196G>C p.A66P | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV99231111; called by muse, mutect2
- MAGEC1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 103/253 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs868561223, COSV53581200; called by muse, mutect2, varscan2
- MDH2 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 126/313 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs140381447; called by muse, mutect2, varscan2
- NPIPB11 | c.3118A>C p.T1040P | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); catalogued as rs191545623; called by muse, varscan2
- NR6A1 | c.803C>T p.T268M (on ENST00000487099 / NM_033334.4; = p.T263M on NM_001489.5) | Missense Mutation (SNP) | VAF 62/483 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs779319203, COSV60630888, COSV60636111; called by muse, mutect2, varscan2
- POM121L2 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 246/539 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1442655770, COSV66275399; called by muse, mutect2, varscan2
- POTEF | c.2229G>T p.M743I | Missense Mutation (SNP) | VAF 283/1152 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV62543084; called by muse, mutect2, varscan2
- PRR12 | c.1702G>A p.A568T (on ENST00000615927; = p.A1389T on NM_020719.3) | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs759563131, COSV69819892; called by muse, mutect2, varscan2
- SARDH | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as rs751832686; called by muse, mutect2, varscan2
- SIN3B | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 85/403 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs749391401, COSV56131887; called by muse, mutect2, varscan2
- STX11 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV62448656; called by muse, mutect2, varscan2
- TRIM69 | c.1483C>T p.H495Y (on ENST00000329464 / NM_182985.5; = p.H336Y on NM_080745.5) | Missense Mutation (SNP) | VAF 76/763 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs1442246522; called by muse, mutect2
- ZC3H7A | c.1351G>T p.V451L | Missense Mutation (SNP) | VAF 66/669 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs761693840; called by muse, mutect2
- ZDHHC13 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 329/941 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs887977644; called by muse, mutect2, varscan2
- AFG3L2 | c.1566dup p.N523* | Frame Shift Ins (INS) | VAF 116/800 reads (15%) | called by mutect2, pindel, varscan2
- ANKRD29 | c.271C>A p.H91N | Missense Mutation (SNP) | VAF 65/742 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANO5 | c.79A>G p.M27V | Missense Mutation (SNP) | VAF 65/1078 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- ARHGAP36 | c.1594G>T p.V532L | Missense Mutation (SNP) | VAF 28/671 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.021); called by muse, mutect2
- AUNIP | c.1007del p.N336Ifs*2 | Frame Shift Del (DEL) | VAF 154/1304 reads (12%) | called by mutect2, pindel, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 48/1524 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- C6orf62 | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 249/1061 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CEP120 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 24/852 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- CEP350 | c.3086_3087del p.K1029Rfs*7 | Frame Shift Del (DEL) | VAF 154/1124 reads (14%) | called by mutect2, pindel, varscan2
- CHPT1 | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 33/1052 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CNGA4 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 140/757 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- COPS2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 45/1020 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.153); called by muse, mutect2
- DOCK7 | c.4675C>T p.R1559* (on ENST00000635253 / NM_001367561.1; = p.R1528* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 224/1009 reads (22%) | called by muse, mutect2, varscan2
- ENKUR | c.319A>T p.N107Y | Missense Mutation (SNP) | VAF 133/932 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- EVI5 | c.1388_1395del p.L463Rfs*9 | Frame Shift Del (DEL) | VAF 108/877 reads (12%) | called by mutect2, pindel, varscan2
- FAM241A | c.254T>G p.M85R | Missense Mutation (SNP) | VAF 266/1390 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- FSIP2 | c.6474_6481del p.D2158Efs*6 | Frame Shift Del (DEL) | VAF 157/917 reads (17%) | called by mutect2, pindel, varscan2
- GARRE1 | c.3038A>T p.Q1013L | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GCNT1 | c.483del p.Y162Ifs*2 | Frame Shift Del (DEL) | VAF 146/941 reads (16%) | called by mutect2, pindel, varscan2
- GOLGA6L2 | c.606A>T p.L202F | Missense Mutation (SNP) | VAF 86/763 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF21A | c.3781_3782dup p.D1262Qfs*24 (on ENST00000361418 / NM_001378440.1; = p.D1249Qfs*24 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 155/960 reads (16%) | called by mutect2, pindel, varscan2
- MMS22L | c.3009G>T p.Q1003H | Missense Mutation (SNP) | VAF 45/822 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PALM3 | c.281A>T p.Q94L (on ENST00000340790; = p.Q109L on NM_001145028.2) | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PAPOLB | c.1765G>C p.A589P | Missense Mutation (SNP) | VAF 36/938 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- SH2D3C | c.989C>A p.A330D (on ENST00000314830 / NM_170600.3; = p.A173D on NM_005489.4) | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); called by muse, mutect2
- SHCBP1L | c.405+1G>A p.X135_splice | Splice Site (SNP) | VAF 46/947 reads (5%) | called by muse, mutect2
- SOAT1 | c.859A>C p.S287R | Missense Mutation (SNP) | VAF 79/631 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPATA45 | c.118_126del p.Q40_S42del | In Frame Del (DEL) | VAF 106/448 reads (24%) | called by pindel, varscan2
- SRI | c.102del p.L35Cfs*8 | Frame Shift Del (DEL) | VAF 89/609 reads (15%) | called by mutect2, pindel, varscan2
- TRAF3IP1 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 254/695 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TTC39A | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 217/469 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- USP32 | c.3080C>T p.T1027I | Missense Mutation (SNP) | VAF 64/1404 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- ZNF32 | c.560del p.K187Sfs*18 | Frame Shift Del (DEL) | VAF 133/828 reads (16%) | called by mutect2, pindel, varscan2
- AKAP4 | c.12C>T p.Y4= | Silent (SNP) | VAF 319/467 reads (68%) | called by muse, mutect2, varscan2
- ALK | c.4215G>T p.V1405= | Silent (SNP) | VAF 174/1078 reads (16%) | called by muse, mutect2, varscan2
- ANHX | c.999C>T p.A333= | Silent (SNP) | VAF 79/492 reads (16%) | called by muse, mutect2, varscan2
- CD99 | c.390T>C p.I130= | Silent (SNP) | VAF 56/375 reads (15%) | catalogued as rs1386451327; called by muse, mutect2, varscan2
- CREB3L2 | c.540G>A p.E180= | Silent (SNP) | VAF 332/1174 reads (28%) | called by muse, mutect2, varscan2
- DENND1A | c.2340C>T p.D780= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as rs377213936; called by muse, mutect2, varscan2
- DUOX2 | c.2338C>T p.L780= | Silent (SNP) | VAF 49/453 reads (11%) | called by muse, mutect2, varscan2
- ERMARD | c.393G>A p.S131= | Silent (SNP) | VAF 366/710 reads (52%) | catalogued as rs377727194; ClinVar: likely benign; called by muse, mutect2, varscan2
- HOXB1 | c.465C>T p.A155= | Silent (SNP) | VAF 58/260 reads (22%) | called by muse, mutect2, varscan2
- IRS2 | c.12G>A p.P4= | Silent (SNP) | VAF 38/300 reads (13%) | called by muse, varscan2
- LIPT2 | c.456C>T p.I152= | Silent (SNP) | VAF 114/473 reads (24%) | catalogued as rs947036591; called by muse, mutect2, varscan2
- NEMP2 | c.978A>G p.S326= | Silent (SNP) | VAF 95/638 reads (15%) | called by muse, mutect2, varscan2
- PPP1R8 | c.963C>G p.V321= (on ENST00000311772 / NM_014110.5; = p.V97= on NM_002713.4) | Silent (SNP) | VAF 271/981 reads (28%) | catalogued as COSV52580660; called by muse, mutect2, varscan2
- PRDM7 | c.735G>T p.G245= | Silent (SNP) | VAF 147/786 reads (19%) | catalogued as COSV57986857; called by muse, mutect2, varscan2
- PSG1 | c.954C>T p.G318= | Silent (SNP) | VAF 60/922 reads (7%) | catalogued as rs1208230524; called by muse, mutect2
- SCN3A | c.2142C>T p.N714= | Silent (SNP) | VAF 206/989 reads (21%) | called by muse, mutect2, varscan2
- SLC26A11 | c.1596C>A p.L532= | Silent (SNP) | VAF 66/389 reads (17%) | called by muse, mutect2, varscan2
- SLC38A11 | c.889T>C p.L297= (on ENST00000409149 / NM_001351539.1; = p.L275= on NM_173512.2) | Silent (SNP) | VAF 112/1503 reads (7%) | catalogued as rs1285720676; called by muse, mutect2
- SLCO3A1 | c.492C>T p.D164= | Silent (SNP) | VAF 68/408 reads (17%) | called by muse, mutect2, varscan2
- THEG | c.978C>T p.V326= | Silent (SNP) | VAF 43/332 reads (13%) | catalogued as rs144210296; called by muse, mutect2, varscan2
- TRIM69 | c.1482G>A p.L494= (on ENST00000329464 / NM_182985.5; = p.L335= on NM_080745.5) | Silent (SNP) | VAF 77/780 reads (10%) | called by muse, mutect2
- TRPC7 | c.1209T>G p.V403= | Silent (SNP) | VAF 50/1147 reads (4%) | called by muse, mutect2
- TSEN54 | c.117C>T p.G39= | Silent (SNP) | VAF 60/349 reads (17%) | called by muse, mutect2, varscan2
- UNC5A | c.2451C>T p.L817= | Silent (SNP) | VAF 36/232 reads (16%) | called by muse, mutect2, varscan2
- ACAT1 | c.940+72_940+76delinsCTT | Intron (DEL) | VAF 26/84 reads (31%) | called by pindel, varscan2*
- ADGRF3 | chr2:26309540 T>C | 3'Flank (SNP) | VAF 86/862 reads (10%) | called by muse, mutect2
- AF241726.1 | c.171+520052T>C | Intron (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2
- AXIN1 | c.2187-49G>T | Intron (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- CCDC183 | c.*5G>T | 3'UTR (SNP) | VAF 15/172 reads (9%) | called by muse, mutect2
- CCDC183 | c.*6C>T | 3'UTR (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2
- COL1A2 | c.-92del | 5'UTR (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- FBXO42 | c.502+29C>T | Intron (SNP) | VAF 234/835 reads (28%) | called by muse, mutect2, varscan2
- IRF9 | c.495+40G>A | Intron (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- LILRB5 | c.1629+28C>A | Intron (SNP) | VAF 28/174 reads (16%) | catalogued as rs1169088060; called by muse, mutect2
- MRRF | c.-23G>A | 5'UTR (SNP) | VAF 66/633 reads (10%) | called by muse, mutect2, varscan2
- MTHFD1L | c.227+312G>A | Intron (SNP) | VAF 48/228 reads (21%) | called by muse, mutect2, varscan2
- NFXL1 | chr4:47843253 del T | 3'Flank (DEL) | VAF 64/482 reads (13%) | called by pindel, varscan2
- PRPF3 | c.1283-82G>A | Intron (SNP) | VAF 28/151 reads (19%) | catalogued as rs1174438113; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.-469G>A | 5'UTR (SNP) | VAF 16/67 reads (24%) | catalogued as rs1206937272; called by muse, mutect2, varscan2
- RIC8A | c.1356-87C>T | Intron (SNP) | VAF 27/156 reads (17%) | called by muse, mutect2, varscan2
- RIMS1 | c.1679-20602A>C | Intron (SNP) | VAF 194/1255 reads (15%) | called by muse, mutect2, varscan2
- SPAG17 | c.5622-41C>T | Intron (SNP) | VAF 170/525 reads (32%) | called by muse, mutect2, varscan2
- TMBIM6 | c.690+85C>T | Intron (SNP) | VAF 56/322 reads (17%) | called by muse, mutect2, varscan2
